Gene-level copy-number profile of tumor specimen C3L-01836-01 from CPTAC case C3L-01836, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.1 years (17,215 days).
Specimen C3L-01836-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cd3094a9-04a7-4b45-a53f-e3040342e404.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01836-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/bb33e034-61fd-474d-a127-0db8886ae370

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,742; copy number 1: 3,128; copy number 2: 51,025; copy number 3: 533; copy number 4: 140; copy number 6: 1,346; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 2,734 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–86,496,996, 1,314 genes (broad region; genes not listed).
- chr6:68,332,019–170,738,536, 1,420 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,347 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,973,599–190,092,279, 20 genes, copy number 6: MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:107,699,392–108,382,098, 5 genes, copy number 6: AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17.
- chr5:113,022,099–181,342,213, 1,321 genes, copy number 6 (broad region; genes not listed).
- chr16:90,173,217–90,222,851, 1 gene, copy number 8 (within-gene range 2–8): LINC02193.

Autosomal genes at a single copy (total copy number 1): 305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
